Somatic mutation profile of tumor specimen TCGA-EU-5904-01A (aliquot TCGA-EU-5904-01A-11D-1669-08) from TCGA case TCGA-EU-5904, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 47.8 years (17,468 days).
Specimen TCGA-EU-5904-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48eda059-5ba7-45cc-a00c-13c45d33d795.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EU-5904-10A (Blood Derived Normal), aliquot TCGA-EU-5904-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c51d318-4721-434d-aa6a-2044f48a2870

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP63 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen possibly damaging (0.664); catalogued as rs147148566, COSV53202265, COSV53220854; called by muse, mutect2, varscan2
- VHL | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs397516444, CM951291, CM951292, COSV56546524, COSV56553028, COSV56557871; ClinVar: pathogenic; called by muse, mutect2
- APBB1IP | c.260A>T p.K87I | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.871); catalogued as COSV63303150; called by muse, mutect2, varscan2
- ATP4A | c.2008G>C p.D670H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV52869527; called by muse, mutect2, varscan2
- CEMIP | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.856); catalogued as COSV54996030; called by muse, mutect2, varscan2
- CNTLN | c.2951T>A p.L984* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV52086091; called by muse, mutect2, varscan2
- DIP2C | c.2489T>A p.F830Y | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55167009; called by muse, mutect2, varscan2
- GPR78 | c.425T>A p.L142H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV66763434, COSV66763868; called by muse, mutect2
- ITGA4 | c.2753A>G p.Q918R | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as COSV67897990; called by muse, mutect2, varscan2
- KIAA0100 | c.2857C>G p.L953V | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66494667; called by muse, mutect2, varscan2
- KIF1B | c.4705G>C p.G1569R (on ENST00000377086 / NM_001365952.1; = p.G1523R on NM_015074.3) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55811604; called by muse, mutect2, varscan2
- KLRG1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV56944193; called by muse, mutect2, varscan2
- KRT39 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 9/190 reads (5%) | catalogued as rs866707936, COSV62917367; called by muse, mutect2
- LRP10 | c.818C>G p.A273G | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as rs1001490526, COSV62078566; called by muse, mutect2, varscan2
- MAPKBP1 | c.1664G>A p.R555Q (on ENST00000456763 / NM_001128608.2; = p.R549Q on NM_014994.3) | Missense Mutation (SNP) | VAF 7/206 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs1361688035, COSV52963135; called by muse, mutect2
- MLH3 | c.600G>C p.Q200H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs942887798, COSV53135427; called by muse, mutect2, varscan2
- MYH4 | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV55121998; called by muse, mutect2
- MYO16 | c.5115G>A p.M1705I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV62754409; called by muse, mutect2, varscan2
- NDUFAF3 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100455158, COSV58245846; called by muse, varscan2
- NRP1 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55171238; called by muse, mutect2, varscan2
- OR10J1 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.026); catalogued as rs1252346033, COSV71129172; called by muse, mutect2
- PDPN | c.93C>G p.D31E (on ENST00000621990; = p.D107E on NM_006474.4) | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as COSV53849227; called by muse, mutect2
- PI4KA | c.2783A>G p.D928G | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55416108; called by muse, mutect2, varscan2
- PPP4R4 | c.2525C>T p.S842F | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.858); catalogued as COSV58553238; called by muse, mutect2, varscan2
- SC5D | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV50613279; called by muse, varscan2
- SIGLEC1 | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV52467532; called by muse, mutect2
- SLX4 | c.428T>A p.V143E | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV53565917; called by muse, mutect2, varscan2
- SPRTN | c.464T>G p.F155C | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50478729; called by muse, mutect2, varscan2
- TMCC2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs747797293, COSV58004915; called by muse, mutect2, varscan2
- UTP4 | c.1745C>G p.P582R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV58733581; called by muse, mutect2, varscan2
- XIRP2 | c.6827C>A p.S2276* (on ENST00000628543; = p.S2451* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | catalogued as COSV54714990; called by muse, mutect2
- XPNPEP2 | c.1594G>T p.V532L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64369541; called by muse, mutect2, varscan2
- GLYR1 | c.807del p.I270* | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- NCAPG | c.918_919dup p.I307Kfs*2 | Frame Shift Ins (INS) | VAF 44/150 reads (29%) | called by mutect2, pindel, varscan2
- PPP1R12A | c.2759dup p.Y920* | Nonsense Mutation (INS) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- TTN | c.46342_46354del p.A15448Hfs*16 (on ENST00000591111; = p.A8024Hfs*16 on NM_003319.4) | Frame Shift Del (DEL) | VAF 53/261 reads (20%) | called by mutect2, pindel, varscan2
- ALDH5A1 | c.1266T>C p.P422= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV62373848; called by muse, mutect2, varscan2
- CCDC85A | c.576C>T p.S192= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV68153351; called by muse, mutect2, varscan2
- CCNQ | c.321C>G p.P107= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV52344931, COSV99368085; called by muse, mutect2, varscan2
- EHMT1 | c.2001C>T p.A667= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs1287856640, COSV58378164; called by muse, mutect2, varscan2
- GCC2 | c.3354C>T p.A1118= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1209968900, COSV59178066; called by muse, mutect2, varscan2
- PCDHGA5 | c.1326A>G p.V442= | Silent (SNP) | VAF 89/212 reads (42%) | catalogued as rs923075599, COSV53983568; called by muse, mutect2, varscan2
- RCBTB2 | c.501A>G p.L167= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as rs199638083, COSV60650767; called by muse, mutect2, varscan2
- TSFM | c.972G>A p.Q324= (on ENST00000323833 / NM_001172696.2; = p.Q303= on NM_005726.6) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV57682681; called by muse, mutect2, varscan2
- TUBA8 | c.867C>A p.A289= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV57813467; called by muse, mutect2, varscan2
- SYT4 | c.-1A>T | 5'UTR (SNP) | VAF 17/71 reads (24%) | catalogued as rs768794450, COSV99673608; called by muse, mutect2, varscan2
